Somatic mutation profile of tumor specimen TCGA-A3-3320-01A (aliquot TCGA-A3-3320-01A-01D-0966-08) from TCGA case TCGA-A3-3320, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 52.4 years (19,138 days).
Specimen TCGA-A3-3320-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f91a3377-a31a-41ae-b521-2278d5698907.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3320-11A (Solid Tissue Normal), aliquot TCGA-A3-3320-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b8f31ca-9eef-433c-8305-ccd67bfe53ab

The open-access MAF lists 90 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 21, Nonsense Mutation 11, Frame Shift Del 8, Intron 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM21 | c.793A>T p.N265Y | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50792468, COSV50805951; called by muse, mutect2, varscan2
- AFTPH | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53221133, COSV99480966; called by muse, mutect2, varscan2
- ARID1A | c.3731C>A p.P1244H | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV61386997, COSV61389998; called by muse, mutect2, varscan2
- BCAR1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV50799373; called by muse, mutect2, varscan2
- BCORL1 | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV54404889; called by muse, mutect2, varscan2
- CA10 | c.634+2T>C p.X212_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | catalogued as COSV53367728; called by muse, mutect2, varscan2
- CAPN15 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54839019; called by muse, mutect2, varscan2
- CEP164 | c.3997C>A p.Q1333K | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV54045581; called by muse, mutect2, varscan2
- COL5A2 | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV66414059; called by muse, mutect2, varscan2
- CPSF1 | c.1740A>T p.E580D | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.199); catalogued as COSV62942086; called by muse, mutect2, varscan2
- DNAH17 | c.6919C>A p.R2307S | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs779251038, COSV67760113; called by muse, mutect2, varscan2
- ECPAS | c.4496T>A p.L1499* | Nonsense Mutation (SNP) | VAF 58/173 reads (34%) | catalogued as COSV52205686; called by muse, mutect2, varscan2
- EIF4E | c.39T>A p.N13K | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.778); catalogued as COSV55188934; called by muse, mutect2, varscan2
- FAM166A | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV61117634; called by muse, mutect2, varscan2
- FLG | c.7424G>C p.G2475A | Missense Mutation (SNP) | VAF 169/717 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs754539573, COSV64247311; called by muse, mutect2, varscan2
- FLRT2 | c.1783A>T p.K595* | Nonsense Mutation (SNP) | VAF 85/222 reads (38%) | catalogued as COSV58148623; called by muse, mutect2, varscan2
- FYB2 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 28/296 reads (9%) | catalogued as COSV58588440; called by muse, mutect2
- GPANK1 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63264103; called by muse, mutect2, varscan2
- HNRNPCL1 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58614570; called by muse, mutect2, varscan2
- ILDR1 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56553098; called by muse, mutect2, varscan2
- ITIH6 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs747260784, COSV54492091; called by muse, mutect2, varscan2
- LHX2 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65318998; called by muse, mutect2, varscan2
- MAST4 | c.7349G>A p.R2450Q (on ENST00000403625 / NM_001164664.2; = p.R2261Q on NM_015183.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as rs576028127, COSV55138852; called by muse, mutect2, varscan2
- NPAS1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV71384290; called by muse, mutect2, varscan2
- NR1H3 | c.1040A>C p.N347T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.756); catalogued as COSV60629041; called by muse, mutect2, varscan2
- NREP | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | catalogued as COSV57406082; called by muse, mutect2, varscan2
- OFD1 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV60798553; called by muse, mutect2
- OIT3 | c.1068C>A p.C356* | Nonsense Mutation (SNP) | VAF 16/147 reads (11%) | catalogued as COSV61827111, COSV61827646; called by muse, mutect2, varscan2
- P2RY13 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV56393648; called by muse, mutect2, varscan2
- PBRM1 | c.1918A>T p.K640* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV56299189; called by muse, mutect2, varscan2
- PDE11A | c.2063T>A p.I688N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV53705963; called by mutect2, varscan2
- PGAM1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58356199; called by muse, mutect2, varscan2
- PGK1 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59372227; called by muse, mutect2, varscan2
- PGLYRP3 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV51952385; called by muse, mutect2, varscan2
- POLR3H | c.548del p.P183Rfs*61 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as COSV99347416; called by mutect2, pindel, varscan2
- PPAN-P2RY11 | c.2195T>C p.L732P | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53455221; called by muse, mutect2, varscan2
- PPFIA1 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV54139820; called by muse, mutect2, varscan2
- PTGDS | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56401275; called by muse, mutect2, varscan2
- PTK2 | c.2088A>T p.R696S | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61790895; called by muse, mutect2, varscan2
- RAB3D | c.482T>A p.F161Y | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV55792805; called by muse, mutect2, varscan2
- RSPO4 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54083590; called by muse, varscan2
- RTL3 | c.867G>T p.W289C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV58184897, COSV58185563; called by muse, mutect2, varscan2
- SEC16A | c.2804A>G p.E935G | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV51538637; called by muse, mutect2, varscan2
- SIM1 | c.1469G>T p.W490L | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV53493880, COSV53495841; called by muse, mutect2, varscan2
- SLC13A4 | c.1598G>A p.C533Y | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62462559; called by muse, mutect2
- SLC33A1 | c.1561G>T p.G521* | Nonsense Mutation (SNP) | VAF 33/125 reads (26%) | catalogued as COSV63947672; called by muse, mutect2, varscan2
- SORL1 | c.3101C>A p.A1034D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV52761126; called by muse, mutect2, varscan2
- SPIRE2 | c.1677C>A p.N559K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV65557380; called by muse, mutect2, varscan2
- TLR8 | c.259C>T p.Q87* (on ENST00000218032 / NM_138636.5; = p.Q105* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 11/229 reads (5%) | catalogued as COSV54320037; called by muse, mutect2
- TMCO4 | c.1690G>C p.G564R | Missense Mutation (SNP) | VAF 88/232 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); catalogued as rs746914600, COSV53876416; called by muse, mutect2, varscan2
- TPTE2 | c.1410C>G p.Y470* (on ENST00000400230 / NM_199254.2; = p.Y393* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV55026847; called by muse, mutect2, varscan2
- TST | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1473264938, COSV50765702; called by muse, mutect2, varscan2
- TVP23C | c.346A>T p.N116Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV56672886; called by muse, mutect2, varscan2
- UHRF1BP1 | c.70A>T p.K24* | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as COSV51959499; called by muse, mutect2, varscan2
- WDR47 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368505822, COSV63059429; called by muse, mutect2
- WDR90 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV53474391; called by muse, mutect2, varscan2
- ZNF714 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV52514964, COSV52515398; called by muse, mutect2, varscan2
- ZNF749 | c.1421A>G p.K474R | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61947944; called by muse, mutect2, varscan2
- AGL | c.4574_4580del p.I1525Rfs*20 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel
- ATR | c.7878del p.A2627Lfs*28 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, varscan2
- KANSL1 | c.1938_1947del p.E647Mfs*20 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- METTL21C | c.219dup p.A74Cfs*45 | Frame Shift Ins (INS) | VAF 39/127 reads (31%) | called by mutect2, pindel, varscan2
- PCGF5 | c.421_422del p.I141Lfs*8 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- PHF10 | c.728del p.L243Cfs*37 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | called by mutect2, varscan2
- PRMT7 | c.1469del p.N490Tfs*21 | Frame Shift Del (DEL) | VAF 51/166 reads (31%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.2849del p.Q950Rfs*9 | Frame Shift Del (DEL) | VAF 46/160 reads (29%) | called by mutect2, pindel, varscan2
- BCAR1 | c.99G>T p.L33= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV50799535; called by muse, mutect2, varscan2
- CHPT1 | c.339T>A p.I113= | Silent (SNP) | VAF 107/313 reads (34%) | catalogued as COSV57534583; called by muse, mutect2, varscan2
- CNBP | c.315C>T p.G105= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV69654958; called by muse, mutect2, varscan2
- GCNT3 | c.129G>A p.E43= | Silent (SNP) | VAF 78/221 reads (35%) | catalogued as rs1200732142, COSV68532446; called by muse, mutect2, varscan2
- GRIN3B | c.1479C>T p.F493= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs369027881; called by muse, mutect2
- HERC1 | c.13593C>A p.T4531= | Silent (SNP) | VAF 53/160 reads (33%) | catalogued as COSV101496845, COSV71249801; called by muse, mutect2, varscan2
- IPO13 | c.2070G>A p.K690= | Silent (SNP) | VAF 44/426 reads (10%) | catalogued as COSV64894960; called by muse, mutect2
- IRF9 | c.291T>A p.V97= | Silent (SNP) | VAF 7/135 reads (5%) | catalogued as COSV60703869; called by muse, mutect2
- ITGB4 | c.3273C>T p.H1091= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV52331573; called by muse, mutect2, varscan2
- KIF19 | c.945C>T p.S315= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV63428828; called by muse, mutect2, varscan2
- LRRC7 | c.24A>G p.G8= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV60564618; called by muse, mutect2, varscan2
- MEI1 | c.3132T>C p.A1044= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV55906645; called by muse, mutect2, varscan2
- MYOF | c.4674C>T p.Y1558= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs1369821282, COSV63709578; called by muse, mutect2
- OR52N2 | c.175C>A p.R59= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as COSV57676448, COSV57677673; called by muse, mutect2, varscan2
- RCOR2 | c.1077G>A p.G359= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV56851301; called by muse, mutect2, varscan2
- SLC7A8 | c.1275G>C p.L425= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1227128995, COSV57555634; called by muse, mutect2, varscan2
- SLC9A4 | c.372C>A p.V124= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV54838180; called by muse, mutect2, varscan2
- TCAP | c.6T>A p.A2= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV54093920; called by muse, mutect2, varscan2
- TTC22 | c.984A>G p.P328= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV64881918; called by muse, mutect2, varscan2
- TTN | c.24327C>T p.H8109= (on ENST00000591111; = p.H7182= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV60288664; called by muse, mutect2, varscan2
- XPO5 | c.2065C>T p.L689= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV54834067; called by muse, mutect2, varscan2
- DLEC1 | c.*7G>A | 3'UTR (SNP) | VAF 49/80 reads (61%) | catalogued as rs369229329; called by muse, mutect2, varscan2
- FMN1 | c.2044-1504A>C | Intron (SNP) | VAF 17/76 reads (22%) | catalogued as COSV57931479; called by muse, mutect2
- TTBK2 | c.823-6328G>T | Intron (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
